Somatic mutation profile of tumor specimen BA2284D (aliquot aq-BA2284D) from BEATAML1.0 case 2555, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with mutated NPM1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 44.8 years (16,379 days).
Specimen BA2284D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 46b3785e-f5f4-445f-bb58-dd3925ef77ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2687D (Solid Tissue Normal), aliquot aq-BA2687D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/64bddf9b-6da0-48be-adab-8f6981a11c47

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FBXL7 | c.1450G>A p.E484K | Missense Mutation (SNP) | VAF 9/16 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs777207361; called by muse, varscan2
- HEPHL1 | c.1437G>T p.K479N | Missense Mutation (SNP) | VAF 41/113 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.139); catalogued as COSV100244357, COSV59891143; called by mutect2, varscan2
- TNFRSF9 | c.620C>T p.T207M | Missense Mutation (SNP) | VAF 50/126 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.107); catalogued as rs555723076, COSV66348671; called by muse, mutect2, varscan2
- TTC28 | c.3250G>T p.G1084* | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | called by muse, mutect2
- TMEM176B | c.729A>G p.E243= | Silent (SNP) | VAF 19/57 reads (33%) | catalogued as rs1341024929; called by muse, mutect2, varscan2
